Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041118-09A.3 (aliquot TARGET-15-SJMPAL041118-09A.3-01D) from TARGET case TARGET-15-SJMPAL041118, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,295 days).
Specimen TARGET-15-SJMPAL041118-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b06b8ba-f4fa-4f5e-8be8-891e7859d5d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041118-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041118-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dffa1d40-2a4a-457e-9f4f-4dbc042300df

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894364, CM061079, COSV55527371, COSV99800760; ClinVar: pathogenic; called by mutect2, varscan2
- CDV3 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs765471317; called by mutect2, varscan2
- GALNT9 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs556119200; called by muse, mutect2, varscan2
- GLUD1 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53280422; called by muse, mutect2, varscan2
- PRR23B | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.556); catalogued as COSV61494180; called by mutect2, varscan2
- RIC8A | c.1328C>A p.T443K (on ENST00000526104 / NM_001286134.1; = p.T449K on NM_021932.5) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1489898584; called by muse, mutect2
- STAB2 | c.3074C>A p.A1025D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as COSV66347436; called by muse, mutect2, varscan2
- ACE | c.3877C>A p.H1293N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by mutect2, varscan2
- ARMCX5-GPRASP2 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- BAZ2B | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CASP8AP2 | c.5393C>A p.T1798N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CDK12 | c.2238C>A p.D746E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- ENTPD6 | c.907C>A p.R303S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- KLF7 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MUC17 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2
- NBEA | c.1819C>A p.H607N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PCDHGA7 | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ADCY10 | c.3435C>T p.G1145= | Silent (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2
- ITPRIPL1 | c.981C>A p.G327= (on ENST00000439118 / NM_001008949.3; = p.G335= on NM_178495.6) | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- LARP1 | c.3073C>A p.R1025= (on ENST00000518297 / NM_033551.3; = p.R948= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- MYBPC2 | c.3366C>A p.A1122= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs770686563; called by mutect2, varscan2
- ZFHX4 | c.8703G>A p.T2901= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1192176251, COSV51480253; called by mutect2, varscan2
